Gene-level copy-number profile of tumor specimen TCGA-DD-A3A5-01A from TCGA case TCGA-DD-A3A5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.5 years (24,288 days).
Specimen TCGA-DD-A3A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.6ecb1b2f-c931-49e7-8669-2536c1ba34e0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A3A5-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9ab98c1-8d32-4599-a5c0-c4bacf4ebf71

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,093; copy number 2: 49,303; copy number 3: 4,089; copy number 4: 101; copy number 5: 1,178; copy number 6: 21; copy number 8: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A3A5-01A-11D-A22E-01): tumor purity 0.87, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,225 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:133,746,040–198,222,513, 1,115 genes, copy number 5 (broad region; genes not listed).
- chr6:43,671,202–44,307,506, 24 genes, copy number 8: MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B.
- chr6:44,278,734–44,313,347, 2 genes, copy number 8: TCTE1, AARS2.
- chr17:18,108,706–18,389,647, 15 genes, copy number 5 (within-gene range 1–5): MYO15A, AC087164.1, ALKBH5, LLGL1, FLII, MIEF2, AC127537.1, TOP3A, RPL7AP65, RPL21P121, SMCR8, SHMT1, MIR6778, EVPLL, AL353997.2.
- chr20:5,750,393–6,528,459, 21 genes, copy number 6: SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20.
- chr22:37,051,736–38,041,915, 48 genes, copy number 5 (within-gene range 3–5): KCTD17, RN7SKP214, TMPRSS6, AL022314.1, IL2RB, Z82188.2, C1QTNF6, SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP, RN7SL385P, LGALS1, NOL12, Z83844.1, TRIOBP, H1-0, GCAT, GALR3, ANKRD54, MIR658, MIR659, EIF3L, AL022311.1, RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534.

Autosomal genes at a single copy (total copy number 1): 5,039. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
